Surgical pathology report (de-identified scan), TCGA case TCGA-23-1032, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1032-01A (Primary Tumor).

[page 1 of 6]
PATHOLOGY REPORT

PATH #:

A/S: F

Rec:

Col:

=====

DIAGNOSIS:

. OMENTUM, ANTERIOR ABDOMINAL WALL, PELVIC TUMOR, LESSER SAC TUMOR, OMENTUM, FALCIFORM LIGAMENT, MESOCOLIC TUMOR, RIGHT GUTTER TUMOR, RIGHT HEPATIC FLEXURE, PERITONEAL TUMOR, RIGHT COLON TUMOR, CUL-DE-SAC TUMOR, RECTOSIGMOID TUMOR, ANTERIOR RECTAL WALL, BLADDER PERITONEUM TUMOR, AND SIGMOID TUMOR (TUMOR DEBULKING):

- Metastatic high grade Mullerian-derived papillary serous carcinoma
- Specimens include fibroadipose, adipose, and fibromuscular tissue infiltrated by carcinoma
- Some of the tissues are mesothelial lined
- Focal skeletal muscle (specimen #3, pelvic tumor) and bladder muscularis (specimen #19, bladder peritoneum tumor) are also noted

6. LIVER (WEDGE RESECTION):

- Liver with metastatic papillary serous carcinoma

13. APPENDIX (APPENDECTOMY):

- Appendix with metastatic papillary serous carcinoma involving serosa and mesoappendix
- Mucosa and muscularis propria with no evidence of carcinoma

14. RIGHT OVARY AND FALLOPIAN TUBE (SALPINGO-OOPHORECTOMY):

- Papillary serous carcinoma involving:
- Ovary (12 cm) with extensive parenchymal and surface involvement
- Paratubal and paraovarian soft tissues
- Fallopian tube is compressed by tumor but no mucosal involvement is identified

15. UTERUS, LEFT FALLOPIAN TUBE (?) AND OVARY (SUPRACERVICAL HYSTERECTOMY, LEFT SALPINGO-OOPHORECTOMY):

- Papillary serous carcinoma involving:
- Ovary (6 cm) with extensive parenchymal and surface

(continued on next page)□

involvement

- Paraovarian soft tissues
- Uterine serosa

[page 2 of 6]
- Fallopian tube not identified
- Atrophic endometrium with a few cystic glands
- Subserosal calcified leiomyoma (0.45 cm)
- Scant endocervical mucosa at inferior cervical resection margin

21. RECTOSIGMOID COLON (SEGMENTAL RESECTION):

- Metastatic papillary serous carcinoma involving colonic serosa and pericolic fat
- Mucosa and muscularis propria with no evidence of carcinoma
- No tumor seen at surgical margins
- Two pericolic lymph nodes with no evidence of metastatic carcinoma (0/2)

22. LEFT ILIAC LYMPH NODE (EXCISION):

- One lymph node with no evidence of metastatic carcinoma (0/1)

23. "RIGHT PELVIC LYMPH NODE" (EXCISION):

- Benign adipose tissue; no lymph node present

NOTE: The adenocarcinoma is similar in all specimens with features of a Mullerian-derived papillary serous carcinoma characterized by high nuclear grade with architectural patterns including papillations, gland formations, cysts, solid nests, and micropapillations. Some of the tumor cells exhibit cytoplasmic vacuolization. Many psammoma bodies, foci of necrosis and acute inflammation, a desmoplastic stromal reaction, and focal lymphovascular invasion are also noted. Some of the specimens show a surface exudate with fibrin, histiocytes, leukocytes, mesothelial cells, and tumor cells.

The patient's prior left breast carcinoma is reviewed, and it does not resemble the current ovarian and abdominal tumor, which is consistent with a new primary.

=====

HISTORY: Ascites, diverticulitis, left breast carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM

Labeled "omentum", received fresh in the Operating Room with tissue taken for clonogenic studies and the remainder fixed in formalin, is an 18 x 7 x 4.5 cm portion of yellow lobulated fatty tissue. The portion of tissue is almost completely replaced by a white-tan firm and focally cystic mass. Cut sections through the mass reveal white-tan, focally hemorrhagic and focally yellow solid areas and also cysts filled with clear and mucoid material. Representative sections are submitted.

- A. Solid and cystic area - 1
- B. Cystic area - 1

(continued on next page)□

2: ANTERIOR ABDOMINAL WALL

Labeled "anterior abdominal wall" and received in formalin is a 3 x 1 x 1 cm portion of white-tan, focally hemorrhagic soft tissue.

- C. Multiple

3: PELVIC TUMOR

Labeled "pelvic tumor" and received in formalin are eight fragments of white-tan, focally hemorrhagic soft tissue ranging from 1.2 to

[page 3 of 6]
5.5 cm and aggregating to 7.5 x 7.5 x 2.5 cm. Representative sections are submitted.

D. 3

4: LESSER SAC TUMOR

Labeled "lesser sac tumor" and received in formalin is a 4.5 x 3.0 x 1.5 cm aggregate of multiple white-tan, firm portions of tissue. Representative sections are submitted.

E. 4

5: OMENTUM

Labeled "omentum" and received in formalin are two 22 x 7 x 4 cm and 22 x 8 x 4 cm portions of fibrofatty and focally hemorrhagic soft tissue. Both portions of tissue are almost completely replaced by white-tan, focally hemorrhagic mass. Representative sections are submitted.

F. 2

6: LIVER TUMOR

Labeled "liver tumor" and received in formalin is a 2.5 x 2.5 x 1.0 cm portion of tan-brown and cauterized soft tissue. Cut sections through the tissue reveal a 1.0 x 1.0 x 1.0 cm white-tan firm nodule and brown-tan soft tissue at the periphery of the nodule. Representative section.

G. 1

7: FALCIFORM LIGAMENT

Labeled "falciform ligament" and received in formalin is a 4.7 x 2.0 x 1.0 cm portion of pink-tan soft tissue. There are multiple white-tan firm nodules identified within the soft tissue. The nodules range from 0.2 to 1.5 cm. Representative sections are submitted.

H. 2

8: MESOCOLIC TUMOR

Labeled "mesocolic tumor" and received in formalin are five portions of white-tan cauterized soft tissue. Portions of tissue range from 0.5 to 1.2 cm. Entirely submitted.

I. 6

9: RIGHT GUTTER TUMOR

Labeled "right gutter tumor" and received in formalin is an 8.5 x 4.0 x 1.5 cm portion of yellow lobulated fibrofatty tissue. Almost the entire specimen is replaced by multiple white-tan firm nodules ranging from 0.2 to 0.5 cm. Representative sections are submitted.

J. 5

10: RIGHT HEPATIC FLEXURE

Labeled "right hepatic flexure" and received in formalin is an 8.0

(continued on next page)□

x 3.0 x 0.7 cm portion of yellow lobulated fatty tissue with a 3.5 x 3.0 cm area of multiple white-tan firm nodules adhered to the fatty tissue. Representative sections are submitted.

K. 3

11: PERITONEAL TUMOR

Labeled "peritoneal tumor" and received in formalin is a 4.0 x 3.0 x 1.2 cm irregular portion of tan, hemorrhagic soft tissue. A portion of tissue is entirely replaced by white-tan firm nodular mass. Representative sections are submitted.

L. 2

12: RIGHT COLON TUMOR

Labeled "right colon tumor" and received in formalin is a 1.2 x 1.0

[page 4 of 6]
x 0.5 cm portion of white-tan firm tissue. Entirely submitted.
M. 2

13: APPENDIX

Labeled "appendix" and received in formalin is a 6.5 cm in length, 0.7 cm in average diameter appendix with a 1.3 cm in width attached periappendiceal fat. Appendiceal serosa is brown-tan and focally hemorrhagic with multiple white-tan firm nodules. Periappendiceal fat is also partially replaced by white-tan firm nodules. Cut section through the appendix reveals a 0.2 cm in thickness white appendiceal wall and up to 0.5 cm in diameter lumen. The appendix is filled with feculent material. Tumor does not grossly invade the appendiceal wall. Representative sections are submitted.

N. 5

14: RIGHT OVARY

Labeled "right ovary" and received in formalin is a 12 x 10 x 6 cm distorted ovary. The surface is variegated with focally hemorrhagic areas and multiple fibrous adhesions. Cut section through the ovary reveals yellow-tan hemorrhagic variegated soft and focally necrotic mass. There is a 9.0 cm in length, 1.0 cm in diameter fallopian tube attached to the ovary. A fimbriated end is not identified. Cut sections through the fallopian tube reveal a 0.2 cm in thickness wall and up to 0.4 cm lumen. Representative sections are submitted.

O-S. 1 each

15: UTERUS, LEFT TUBE AND OVARY

Labeled "uterus, left tube and ovary" and received in formalin is a supracervical hysterectomy with attached adnexa. The uterus and ovary weigh 70 grams. The uterus measures 4.5 cm superior to excisional cervical margin, 5.0 cm cornu to cornu, and 2.0 cm anterior to posterior. The uterine serosa is pink-tan with multiple serous adhesions which contain multiple white-tan and firm nodules. There is also a 1.0 cm in diameter white-tan firm serosal nodule. The uterus is incised on both sides. Cut section reveals a 3.5 cm in length, up to 1.5 cm in width uterine cavity. The endometrium is pink-tan, grossly unremarkable, and ranges in width from 0.1 to 0.2 cm. The myometrium is pink-tan, grossly unremarkable, and measures up to 1.5 cm in thickness. The attached left adnexa measures 6 x 3.5 x 1.5 cm consisting of a variegated, focally hemorrhagic mass. The fallopian tube is not definitively identified. There is a smaller 3.0 x 1.5 x 1.0 cm white-tan firm mass which is loosely attached to the already described mass.

(continued on next page)□

Representative sections are submitted.

T. Posterior lower uterine segment - 1

U. Anterior lower uterine segment - 1

V. Anterior corpus - 1

W. Posterior corpus

X. Posterior lower uterine segment and serosal adhesions - 2

Y-AA. Ovarian and tubal mass - 1 each

BB. Smaller firm mass - 2

ADDITIONAL SECTION

MM. Possible fallopian tube - 4

16: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is a 9.5 x 7.5 x 3.5 cm aggregate of white-tan firm tumor and clotted blood. Representative sections are submitted.

CC. 2

17: RECTAL SIGMOID TUMOR

[page 5 of 6]
Labeled "rectal sigmoid tumor" and received in formalin is a 4.5 x 2.5 x 0.5 cm irregular portion of tan, focally hemorrhagic soft tissue. There is a 1 x 1 cm white-tan firm area at one surface of the tissue. Representative sections are submitted.
DD. 3

18: ANTERIOR RECTAL WALL

Labeled "anterior rectal wall" and received in formalin are four portions of white-tan soft tissue ranging from 0.7 to 1.5 cm. Entirely submitted.
EE. Multiple

19: BLADDER PERITONEUM AND TUMOR

Labeled "bladder peritoneum and tumor" and received in formalin are five portions of yellow lobulated fatty tissue almost entirely replaced by white-tan and firm tumor nodules which range from 0.2 to 2.0 cm. Representative sections are submitted.
FF. 3

20: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin are two 2.0 and 1.0 cm portions of white-tan soft tissue. Entirely submitted.
GG. 2

21: RECTAL SIGMOID COLON

Labeled "rectal sigmoid colon" and received in formalin is a 4.5 cm in length, 5 cm in opened circumference segment of colon with a 5.5 cm in width portion of attached pericolic fat. The serosa is pink-tan and smooth with multiple small white-tan nodules attached to the serosa and in the pericolic fat. The wall measures 0.3 cm in thickness and is grossly unremarkable. The mucosal folds are grossly unremarkable and no lesions are identified. Representative sections are submitted.

HH. Serosal nodule

II. Margins

JJ. Pericolic fat with nodules - Multiple

22: LEFT ILLIAC LYMPH NODE

Labeled "left iliac lymph node" and received in formalin is a 0.9 x (continued on next page)□

0.4 x 0.3 cm lymph node. Entirely submitted.
KK. 2

23: RIGHT PELVIC LYMPH NODE

Labeled "right pelvic lymph node" and received in formalin are two 1.0 x 0.9 x 0.9 cm portions of fatty lobulated tissue. No grossly identifiable lymph node is present. Entirely submitted.
LL. Multiple

Gross dictated by

OPERATIVE CONSULT (GROSS):

1. OMENTUM:

-Three pieces, each 1.5 cm in greatest dimension were taken for the extreme drug resistance testing

(

Special Studies: None

See Also:

[page 6 of 6]
I, _____, the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Source: NCI Genomic Data Commons file b8677675-5404-4813-98a9-f5d9ac28a936 (TCGA-23-1032.6E8A5413-EB7E-49D8-8E11-8CA6A912ED50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).